Somatic mutation profile of tumor specimen 0DJA07 from CCDI case PBBWSN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain stem; Age at diagnosis: 4.4 years (1,600 days).
Specimen 0DJA07: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ada80520-0637-48c1-bcbc-726957f7fc72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ9ZV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3655821f-43e6-42aa-af88-ce4ba51fa2de

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 182/763 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PSMD1 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 112/721 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs745401053, COSV58084059; called by muse, mutect2, varscan2
- RIF1 | c.6883T>C p.L2295= | Silent (SNP) | VAF 37/1000 reads (4%) | catalogued as rs763245776, COSV54624375; called by muse, mutect2
- DCHS2 | n.1169G>T | RNA (SNP) | VAF 89/698 reads (13%) | called by muse, mutect2, varscan2
- MUC17 | c.*1G>A | 3'UTR (SNP) | VAF 40/600 reads (7%) | called by muse, mutect2
